Somatic mutation profile of tumor specimen C3N-01905-01 (aliquot CPT0124210006) from CPTAC case C3N-01905, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.2 years (21,631 days).
Specimen C3N-01905-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e609ae43-8ca6-40cd-84ab-5a95bd75b2de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01905-31 (Blood Derived Normal), aliquot CPT0124340002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ddba38d-ad73-4d70-9b6c-47683d742403

The open-access MAF lists 114 somatic variants for this specimen: 79 protein-altering or splice-affecting, 20 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 20, Intron 8, Frame Shift Del 6, Nonsense Mutation 3, Frame Shift Ins 3, 3'UTR 3, RNA 2, Splice Site 2, 3'Flank 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM12 | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 142/539 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64108343; called by muse, mutect2, varscan2
- ANKS1B | c.1687C>G p.P563A | Missense Mutation (SNP) | VAF 37/383 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.986); catalogued as rs771962477; called by muse, mutect2
- BRSK1 | c.1863A>T p.K621N | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58664628; called by muse, mutect2, varscan2
- CAPN5 | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV53687392, COSV99581972; called by muse, mutect2, varscan2
- CNTNAP2 | c.3622G>A p.E1208K | Missense Mutation (SNP) | VAF 93/510 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1325468046, COSV62182949; called by muse, mutect2, varscan2
- DCHS1 | c.7348G>A p.V2450M | Missense Mutation (SNP) | VAF 42/272 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as rs375759882; called by muse, mutect2, varscan2
- GCKR | c.1021A>T p.I341F | Missense Mutation (SNP) | VAF 42/704 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV53110244; called by muse, mutect2
- IL12RB2 | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 89/608 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs759592157, COSV52027427; called by muse, mutect2, varscan2
- LIN7A | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54020298; called by muse, mutect2
- MS4A1 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 30/597 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs188842906, COSV61943004; called by muse, mutect2
- OR2AT4 | c.143C>A p.A48D | Missense Mutation (SNP) | VAF 28/375 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.388); catalogued as COSV100532276; called by muse, mutect2
- OR2AT4 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.009); catalogued as rs1171394617; called by muse, mutect2
- OTOF | c.2689C>T p.R897W (on ENST00000272371 / NM_194248.3; = p.R150W on NM_004802.4) | Missense Mutation (SNP) | VAF 39/519 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768666917, COSV55499483; called by muse, mutect2
- PCDHGA9 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.424); catalogued as rs763967342; called by muse, mutect2
- R3HDM1 | c.1616del p.F539Sfs*6 | Frame Shift Del (DEL) | VAF 19/130 reads (15%) | catalogued as rs1163689562; called by mutect2, pindel, varscan2
- SLAMF1 | c.638A>G p.N213S | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52498149; called by muse, mutect2
- SPECC1 | c.1406A>G p.K469R | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99821694; called by muse, mutect2, varscan2
- TCTEX1D4 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 52/603 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1184799377; called by muse, mutect2
- TJP1 | c.4087G>T p.D1363Y | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62042506, COSV62042978; called by muse, mutect2
- TNPO3 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 20/161 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs373570876; called by muse, mutect2, varscan2
- VHL | c.266T>G p.L89R | Missense Mutation (SNP) | VAF 151/725 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as CM941368, COSV56543066, COSV56543312, COSV56543561; called by muse, mutect2, varscan2
- ZNF324B | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 34/314 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as COSV60743217; called by muse, mutect2, varscan2
- AC011462.1 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 21/553 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTR10 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.119); called by muse, mutect2
- ANKRD31 | c.1597G>T p.G533* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- AP002512.3 | c.740T>C p.L247P | Missense Mutation (SNP) | VAF 25/315 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2
- AP1B1 | c.194T>A p.L65Q | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP2A2 | c.813A>G p.P271= | Splice Region (SNP) | VAF 42/183 reads (23%) | called by muse, mutect2, varscan2
- AP3B1 | c.1705G>A p.D569N | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD11 | c.2001G>T p.Q667H (on ENST00000280758 / NM_001018072.2; = p.Q204H on NM_001017523.2) | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CDH11 | c.1668del p.R557Vfs*16 | Frame Shift Del (DEL) | VAF 38/194 reads (20%) | called by mutect2, pindel
- CGRRF1 | c.318dup p.L107Ifs*3 | Frame Shift Ins (INS) | VAF 15/139 reads (11%) | called by mutect2, pindel
- DAGLA | c.419T>A p.V140D | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, varscan2
- DAGLA | c.2984G>T p.S995I | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- EHBP1 | c.3583G>T p.D1195Y | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF3L | c.9T>A p.Y3* | Nonsense Mutation (SNP) | VAF 34/212 reads (16%) | called by muse, mutect2, varscan2
- FGG | c.265G>C p.A89P | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.093); called by muse, mutect2
- FSIP1 | c.1611C>G p.F537L | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HSPA1A | c.1847dup p.P617Sfs*22 | Frame Shift Ins (INS) | VAF 56/472 reads (12%) | called by mutect2, varscan2
- INPP5F | c.1421G>C p.R474T | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- LAT | c.311-2A>G p.X104_splice | Splice Site (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
- MC3R | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 62/482 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MON2 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 23/335 reads (7%) | called by muse, mutect2
- MOV10L1 | c.527dup p.P177Afs*14 | Frame Shift Ins (INS) | VAF 57/500 reads (11%) | called by mutect2, pindel, varscan2
- MRTFB | c.1478C>A p.A493E | Missense Mutation (SNP) | VAF 51/789 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2
- MYPN | c.1447A>T p.I483F | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOD2 | c.2723del p.G908Afs*22 | Frame Shift Del (DEL) | VAF 113/490 reads (23%) | called by mutect2, pindel, varscan2
- NRIP2 | c.39del p.S14Pfs*22 | Frame Shift Del (DEL) | VAF 23/179 reads (13%) | called by mutect2, pindel, varscan2
- PBRM1 | c.3010del p.T1004Hfs*10 | Frame Shift Del (DEL) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- PCDH10 | c.1067C>A p.P356Q | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- PIK3R1 | c.2108T>G p.L703R (on ENST00000521381 / NM_181523.3; = p.L433R on NM_181504.4) | Missense Mutation (SNP) | VAF 70/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- POMGNT1 | c.1297A>G p.T433A | Missense Mutation (SNP) | VAF 99/596 reads (17%) | PolyPhen benign (0.179); called by muse, mutect2, varscan2
- PPP2CA | c.874G>T p.A292S | Missense Mutation (SNP) | VAF 18/378 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.036); called by muse, mutect2
- PPP2R2B | c.129C>A p.D43E (on ENST00000394409; = p.D109E on NM_181674.2) | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PRPF40B | c.1576G>T p.D526Y (on ENST00000380281; = p.D520Y on NM_012272.3) | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRRT3 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTK2B | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RAD51AP2 | c.1181A>C p.N394T | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBM33 | c.3464+1G>C p.X1155_splice | Splice Site (SNP) | VAF 26/219 reads (12%) | called by muse, mutect2, varscan2
- RFPL3 | c.483G>T p.E161D (on ENST00000249007 / NM_001098535.1; = p.E132D on NM_006604.2) | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ROBO1 | c.3437C>T p.T1146I | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- SCAPER | c.1796T>C p.L599P | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); called by muse, mutect2
- SMC3 | c.896T>C p.I299T | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- SPATA4 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); called by muse, mutect2
- SPTA1 | c.5659A>C p.N1887H | Missense Mutation (SNP) | VAF 57/456 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SRP72 | c.926A>C p.N309T | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SYNE1 | c.7336C>A p.L2446I (on ENST00000367255 / NM_182961.4; = p.L2453I on NM_033071.3) | Missense Mutation (SNP) | VAF 71/530 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TBX5 | c.1361T>A p.M454K | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by muse, mutect2
- TIGIT | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 104/416 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- TSR1 | c.619del p.L207* | Frame Shift Del (DEL) | VAF 30/224 reads (13%) | called by pindel, varscan2
- UBE3A | c.1105G>T p.V369F | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- UNC79 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- USP11 | c.1828C>G p.L610V (on ENST00000218348; = p.L567V on NM_001371072.1) | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- VPS52 | c.1348G>T p.V450F | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ZBTB10 | c.497A>T p.D166V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZCCHC2 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.253); called by muse, mutect2
- ZNF212 | c.1102C>G p.L368V | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2
- ZNF319 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 112/426 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.223); called by mutect2, varscan2
- ZNF883 | c.958C>G p.P320A | Missense Mutation (SNP) | VAF 40/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ALG3 | c.28C>A p.R10= | Silent (SNP) | VAF 61/291 reads (21%) | catalogued as rs563516937; called by muse, mutect2, varscan2
- AP002512.3 | c.741C>A p.L247= | Silent (SNP) | VAF 24/312 reads (8%) | called by muse, mutect2
- ASAP3 | c.1734A>G p.P578= | Silent (SNP) | VAF 76/458 reads (17%) | called by muse, mutect2, varscan2
- ATP6V1E2 | c.609A>T p.S203= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- C2orf81 | c.45C>G p.V15= | Silent (SNP) | VAF 38/209 reads (18%) | called by muse, mutect2, varscan2
- CFAP44 | c.1671G>T p.R557= | Silent (SNP) | VAF 78/362 reads (22%) | called by muse, mutect2, varscan2
- FAT4 | c.6177T>C p.I2059= | Silent (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- G2E3 | c.585T>C p.S195= | Silent (SNP) | VAF 34/218 reads (16%) | called by muse, mutect2, varscan2
- HCAR1 | c.858C>T p.P286= | Silent (SNP) | VAF 40/477 reads (8%) | called by muse, mutect2
- KDM5A | c.1671G>A p.Q557= | Silent (SNP) | VAF 66/578 reads (11%) | called by muse, mutect2, varscan2
- KMT2E | c.1944T>C p.T648= | Silent (SNP) | VAF 68/492 reads (14%) | called by muse, mutect2, varscan2
- KREMEN2 | c.1281C>A p.A427= (on ENST00000303746 / NM_172229.3; = p.P401H on NM_024507.4) | Silent (SNP) | VAF 32/354 reads (9%) | called by muse, mutect2
- MBD6 | c.951C>T p.P317= | Silent (SNP) | VAF 17/345 reads (5%) | catalogued as COSV63073423; called by muse, mutect2
- MTCL1 | c.1815G>A p.Q605= (on ENST00000306329 / NM_001378206.1; = p.Q245= on NM_015210.4) | Silent (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- PTPRQ | c.5982G>A p.L1994= (on ENST00000616559; = p.L1952= on NM_001145026.2) | Silent (SNP) | VAF 36/282 reads (13%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1401G>T p.V467= | Silent (SNP) | VAF 93/450 reads (21%) | called by muse, mutect2, varscan2
- SLFN14 | c.1377C>T p.L459= | Silent (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- TRAM2 | c.1086A>T p.P362= | Silent (SNP) | VAF 37/273 reads (14%) | called by muse, mutect2, varscan2
- TRPM2 | c.480G>A p.Q160= | Silent (SNP) | VAF 48/363 reads (13%) | catalogued as COSV100308572; called by muse, mutect2, varscan2
- URB1 | c.402C>T p.L134= | Silent (SNP) | VAF 20/120 reads (17%) | called by muse, mutect2, varscan2
- ACAD10 | c.2818-68C>A | Intron (SNP) | VAF 50/270 reads (19%) | called by muse, mutect2, varscan2
- AP5S1 | c.*2T>C | 3'UTR (SNP) | VAF 32/132 reads (24%) | called by muse, mutect2, varscan2
- APTX | c.*538C>G | 3'UTR (SNP) | VAF 45/372 reads (12%) | catalogued as rs762743887; called by muse, mutect2, varscan2
- CCNQP1 | n.59T>A | RNA (SNP) | VAF 67/396 reads (17%) | called by muse, mutect2, varscan2
- CDKL1 | c.171+17472T>C | Intron (SNP) | VAF 48/333 reads (14%) | called by muse, mutect2, varscan2
- CHD4 | c.4642+83A>C | Intron (SNP) | VAF 38/298 reads (13%) | called by muse, mutect2, varscan2
- CLN5 | chr13:76991940 C>G | 5'Flank (SNP) | VAF 47/438 reads (11%) | called by muse, mutect2, varscan2
- CSH1 | c.10+43G>A | Intron (SNP) | VAF 37/296 reads (13%) | catalogued as rs763637921; called by muse, mutect2, varscan2
- DCXR | c.449-32C>T | Intron (SNP) | VAF 94/589 reads (16%) | called by muse, mutect2, varscan2
- DGUOK | c.142+5576C>T | Intron (SNP) | VAF 14/188 reads (7%) | catalogued as rs1369490948; called by muse, mutect2
- ESPNP | n.1480G>A | RNA (SNP) | VAF 20/129 reads (16%) | called by muse, varscan2
- FBXO9 | c.*300T>A | 3'UTR (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- KRT15 | c.581+13G>A | Intron (SNP) | VAF 59/424 reads (14%) | catalogued as rs774839034; called by muse, mutect2, varscan2
- PPFIBP2 | c.1376-422C>A | Intron (SNP) | VAF 30/297 reads (10%) | called by muse, mutect2, varscan2
- STAU2 | chr8:73420183 G>T | 3'Flank (SNP) | VAF 25/247 reads (10%) | called by muse, mutect2, varscan2
